Gene-level copy-number profile of tumor specimen TCGA-BK-A0CA-01B from TCGA case TCGA-BK-A0CA, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.3 years (22,378 days).
Specimen TCGA-BK-A0CA-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.e488e03b-31e3-4e7f-87a4-6e30612add04.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BK-A0CA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 353 have no estimate.
https://portal.gdc.cancer.gov/files/771a6287-77c4-45e7-b589-92b3a3ef1f3b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 587; copy number 2: 59,579; copy number 3: 58; copy number 4: 13; copy number 5: 7; copy number 6: 2; copy number 7: 3; copy number 8: 12; copy number 9: 3; copy number 12: 1.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BK-A0CA-01A-21D-A275-01): tumor purity 0.56, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:159,062,484–159,147,096, 1 gene (within-gene range 0–2): AIM2.
- chr6:151,411,259–151,413,945, 1 gene (within-gene range 0–2): HSPA8P15.
- chr8:142,910,559–142,917,843, 1 gene: CYP11B2.
- chr17:2,322,396–2,336,657, 2 genes: TSR1, SNORD91A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 28 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:98,660,388–98,661,059, 1 gene, copy number 5: AC095031.1.
- chr3:116,360,024–116,370,090, 1 gene, copy number 6: LSAMP-AS1.
- chr4:154,754,756–154,781,873, 2 genes, copy number 5: AC009567.1, AC009567.2.
- chr4:154,787,118–154,790,484, 2 genes, copy number 5: RNU2-66P, RNU2-44P.
- chr6:31,479,973–31,511,124, 3 genes, copy number 9: MICB-DT, MICB, Y_RNA.
- chr8:38,223,957–38,275,558, 2 genes, copy number 7 (within-gene range 2–7): AC084024.4, DDHD2.
- chr8:54,354,168–54,355,118, 1 gene, copy number 6: AC027250.1.
- chr10:93,893,973–93,956,062, 1 gene, copy number 7 (within-gene range 2–7): SLC35G1.
- chr13:48,316,863–48,320,475, 1 gene, copy number 12: PPP1R26P1.
- chr14:70,906,657–70,907,111, 1 gene, copy number 8: AC004825.2.
- chr15:25,062,333–25,081,378, 11 genes, copy number 8: SNORD116-5, SNORD116-6, SNORD116-7, SNORD116-8, SNORD116-9, SNORD116-10, SNORD116-11, SNORD116-12, SNORD116-13, SNORD116-14, SNORD116-15.
- chr20:45,435,272–45,481,532, 2 genes, copy number 5 (within-gene range 2–5): AL031663.3, WFDC2.

Autosomal genes at a single copy (total copy number 1): 62. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
